Gene-level copy-number profile of tumor specimen HTMCP-03-06-02225-01A from CGCI case HTMCP-03-06-02225, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02225-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f10621a-2e67-4ab0-a220-51b2d3a4cb31.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02225-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/642f7bf2-1c17-4e6d-bbe5-74ce5282899c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3; copy number 2: 351; copy number 3: 32,906; copy number 4: 17,887; copy number 5: 2,155; copy number 6: 1,739; copy number 7: 2,460; copy number 8: 696; copy number 9: 1; copy number 10: 46; copy number 12: 67; copy number 14: 9; copy number 15: 20; copy number 16: 10; copy number 21: 15; copy number 27: 12.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–3): RNU6-904P, RPS16P3.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–3): AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,336 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 7–8 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 14: TRGC2.
- chr7:38,256,337–38,330,935, 13 genes, copy number 14–15 (within-gene range 6–15): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr7:142,626,649–142,802,748, 30 genes, copy number 10: TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr12:12,310–34,249,958, 834 genes, copy number 7–9 (broad region; genes not listed).
- chr14:21,997,539–22,501,663, 63 genes, copy number 10–27 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 21: TRAC.
- chr22:18,361,820–19,667,555, 72 genes, copy number 8 (broad region; genes not listed).
- chr22:20,495,913–32,285,131, 569 genes, copy number 7–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
